Somatic mutation profile of tumor specimen MMRF_1790_3_BM_CD138pos (aliquot MMRF_1790_3_BM_CD138pos_T1_KHS5U_L14850) from MMRF case MMRF_1790, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.8 years (28,045 days).
Specimen MMRF_1790_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 15fb6b33-4253-4852-b315-8f32a866868e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1790_1_PB_WBC (Blood Derived Normal), aliquot MMRF_1790_1_PB_WBC_C3_KBS5U_L07232; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18409b92-7db4-432b-bf39-7b27cc21a700

The open-access MAF lists 110 somatic variants for this specimen: 48 protein-altering or splice-affecting, 13 silent, 49 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, 3'UTR 27, Silent 13, Intron 8, 5'UTR 6, 3'Flank 4, Splice Site 3, RNA 2, 5'Flank 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MYC | c.173C>T p.T58I (on ENST00000377970; = p.T73I on NM_002467.6) | Missense Mutation (SNP) | VAF 127/223 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756091827, COSV52367994, COSV52373588; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL7B | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as rs139165156; called by muse, mutect2, varscan2
- ADAT3 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 88/197 reads (45%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs758520906; called by muse, mutect2, varscan2
- ANXA1 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99973838; called by muse, mutect2, varscan2
- CIAPIN1 | c.539A>G p.K180R | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs1408790486; called by muse, mutect2, varscan2
- DHRS4L2 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 26/153 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.066); catalogued as rs772988441; called by muse, mutect2, varscan2
- DNAI3 | c.446T>G p.V149G | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as rs1409802552; called by muse, mutect2, varscan2
- DNASE1L1 | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 41/221 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.05); catalogued as rs782288295; called by muse, mutect2, varscan2
- DPP6 | c.692G>A p.S231N (on ENST00000377770 / NM_001364500.2; = p.S169N on NM_001936.5) | Missense Mutation (SNP) | VAF 58/162 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs538699484; called by muse, mutect2
- EGF | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 95/232 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs768471434; called by muse, mutect2, varscan2
- ESPL1 | c.4844C>T p.A1615V | Missense Mutation (SNP) | VAF 43/325 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as rs778039130; called by muse, mutect2, varscan2
- FRAS1 | c.4951C>T p.R1651* | Nonsense Mutation (SNP) | VAF 23/50 reads (46%) | catalogued as rs753960106, COSV99347169, COSV99347494; called by muse, mutect2, varscan2
- IRF4 | c.296G>C p.C99S | Missense Mutation (SNP) | VAF 98/232 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66705766; called by muse, mutect2, varscan2
- ITFG1 | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV100278612; called by muse, mutect2, varscan2
- KCNB1 | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1338339252, COSV65568401; called by muse, mutect2, varscan2
- LINGO2 | c.214G>A p.V72I | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.015); catalogued as rs781520934, COSV58057149; called by muse, mutect2, varscan2
- MAML2 | c.3313G>A p.D1105N | Missense Mutation (SNP) | VAF 11/205 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as rs1260898115; called by muse, mutect2
- PRRT4 | c.2389G>A p.A797T | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs867388733; called by muse, mutect2, varscan2
- REXO5 | c.561G>C p.L187F | Missense Mutation (SNP) | VAF 41/291 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV54472571; called by muse, mutect2, varscan2
- TRIP11 | c.677G>A p.S226N | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as rs771200141; called by muse, mutect2, varscan2
- AL645922.1 | c.109C>T p.L37F | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ALAS2 | c.1434C>G p.I478M | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ANKRD35 | c.601G>A p.V201M | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOC | c.578A>T p.E193V | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); called by muse, mutect2
- BSPH1 | c.260T>G p.F87C | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CLCNKA | c.956T>G p.L319R | Missense Mutation (SNP) | VAF 10/182 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- CNKSR2 | c.1831-1G>T p.X611_splice | Splice Site (SNP) | VAF 28/81 reads (35%) | called by muse, mutect2, varscan2
- CNKSR2 | c.1831G>T p.D611Y | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DAAM1 | c.3180T>G p.I1060M | Missense Mutation (SNP) | VAF 158/345 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- DNAH10 | c.1114G>C p.E372Q (on ENST00000409039; = p.E311Q on NM_207437.3) | Missense Mutation (SNP) | VAF 98/254 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ECPAS | c.3020A>G p.Y1007C | Missense Mutation (SNP) | VAF 13/326 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- EDNRA | c.207C>G p.C69W | Missense Mutation (SNP) | VAF 13/459 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FN1 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 21/222 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HPGD | c.421+2T>G p.X141_splice | Splice Site (SNP) | VAF 21/156 reads (13%) | called by muse, mutect2, varscan2
- HUWE1 | c.2261+1G>A p.X754_splice | Splice Site (SNP) | VAF 27/68 reads (40%) | called by muse, mutect2, varscan2
- IFNAR1 | c.593A>T p.Y198F | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGHD1-7 | c.5T>G p.I2R | Missense Mutation (SNP) | VAF 31/40 reads (78%) | PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KCNN2 | c.1105T>G p.Y369D (on ENST00000264773; = p.Y581D on NM_021614.4) | Missense Mutation (SNP) | VAF 173/416 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.518); called by muse, mutect2, varscan2
- MALRD1 | c.200G>T p.C67F | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MXRA5 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 56/125 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); called by muse, mutect2, varscan2
- NYNRIN | c.1462C>A p.Q488K | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- PRKD2 | c.1688G>C p.G563A | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PSMB9 | c.179_191del p.R60Hfs*25 | Frame Shift Del (DEL) | VAF 8/58 reads (14%) | called by pindel, varscan2
- PTX4 | c.887C>T p.A296V (on ENST00000447419 / NM_001328608.2; = p.A291V on NM_001013658.1) | Missense Mutation (SNP) | VAF 69/171 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- RETREG1 | c.38G>A p.G13E | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, varscan2
- RNF10 | c.719G>A p.C240Y | Missense Mutation (SNP) | VAF 35/194 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLU7 | c.1396T>A p.S466T | Missense Mutation (SNP) | VAF 74/157 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TPTE | c.1586C>T p.S529L (on ENST00000618007 / NM_199261.4; = p.S511L on NM_199259.4) | Missense Mutation (SNP) | VAF 200/1217 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- AC099489.1 | c.3273G>T p.R1091= | Silent (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- ARHGAP26 | c.2340C>T p.G780= | Silent (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2
- CLCN6 | c.1920C>T p.R640= | Silent (SNP) | VAF 75/146 reads (51%) | catalogued as rs142493749; called by muse, mutect2, varscan2
- EGR2 | c.579C>A p.T193= | Silent (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- FECH | c.186G>A p.P62= | Silent (SNP) | VAF 26/65 reads (40%) | catalogued as rs550820935, COSV100023356, COSV50490537; called by muse, mutect2, varscan2
- GTF3C1 | c.5808T>C p.S1936= | Silent (SNP) | VAF 109/262 reads (42%) | called by muse, varscan2
- MACF1 | c.10332A>G p.Q3444= | Silent (SNP) | VAF 81/199 reads (41%) | called by muse, mutect2, varscan2
- MAGEH1 | c.513G>C p.S171= | Silent (SNP) | VAF 94/240 reads (39%) | catalogued as rs1477245374; called by muse, mutect2, varscan2
- NR1D1 | c.981C>G p.T327= | Silent (SNP) | VAF 21/162 reads (13%) | called by muse, mutect2, varscan2
- NSMCE3 | c.222C>T p.A74= | Silent (SNP) | VAF 93/190 reads (49%) | called by muse, mutect2, varscan2
- SLFN12L | c.1545G>C p.S515= (on ENST00000260908 / NM_001363830.1; = p.S533= on NM_001195790.1) | Silent (SNP) | VAF 25/194 reads (13%) | catalogued as rs750552108, COSV53471218, COSV99610120; called by muse, mutect2, varscan2
- SNTN | c.318C>A p.I106= | Silent (SNP) | VAF 63/157 reads (40%) | called by muse, mutect2, varscan2
- UNC80 | c.2874C>T p.A958= | Silent (SNP) | VAF 26/52 reads (50%) | catalogued as rs756648889; called by muse, varscan2
- APEX2 | c.*1237A>G | 3'UTR (SNP) | VAF 53/117 reads (45%) | called by muse, mutect2
- ARMC10P1 | n.791C>G | RNA (SNP) | VAF 50/143 reads (35%) | called by muse, mutect2, varscan2
- ATF4 | c.-92del | 5'UTR (DEL) | VAF 20/66 reads (30%) | called by pindel, varscan2
- BCL7A | chr12:122021118 C>T | 5'Flank (SNP) | VAF 85/205 reads (41%) | catalogued as COSV55851758; called by muse, mutect2, varscan2
- CCNL1 | chr3:157160676 C>A | 5'Flank (SNP) | VAF 31/80 reads (39%) | called by muse, mutect2, varscan2
- CDH12 | c.*364A>T | 3'UTR (SNP) | VAF 41/109 reads (38%) | called by muse, mutect2, varscan2
- CUBN | c.*460C>A | 3'UTR (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2
- CYP2A7P2 | n.494C>T | RNA (SNP) | VAF 45/141 reads (32%) | called by muse, mutect2, varscan2
- ELP3 | c.*653T>G | 3'UTR (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- ENTPD7 | c.*612A>G | 3'UTR (SNP) | VAF 47/107 reads (44%) | called by muse, mutect2, varscan2
- ETV1 | chr7:13894071 ins G | 3'Flank (INS) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- FAM107A | c.*2012G>C | 3'UTR (SNP) | VAF 19/125 reads (15%) | called by muse, mutect2, varscan2
- GBP6 | c.*304T>C | 3'UTR (SNP) | VAF 4/18 reads (22%) | catalogued as rs1557545091; called by muse, mutect2
- GID4 | c.*1815G>A | 3'UTR (SNP) | VAF 8/174 reads (5%) | called by muse, mutect2
- GNRH1 | c.-502A>T | 5'UTR (SNP) | VAF 10/70 reads (14%) | called by muse, mutect2, varscan2
- GPR158 | c.-193G>T | 5'UTR (SNP) | VAF 71/206 reads (34%) | catalogued as rs772745398; called by muse, mutect2, varscan2
- H2BC21 | c.*166G>A | 3'UTR (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- HAUS3 | c.*655A>C | 3'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- HS3ST1 | c.*1286G>A | 3'UTR (SNP) | VAF 41/112 reads (37%) | catalogued as rs1440186295; called by muse, mutect2, varscan2
- KRTAP19-5 | c.*143C>T | 3'UTR (SNP) | VAF 48/118 reads (41%) | called by muse, mutect2, varscan2
- MACC1 | chr7:20137538 C>T | 3'Flank (SNP) | VAF 19/130 reads (15%) | called by muse, mutect2, varscan2
- MDGA2 | c.*1329G>A | 3'UTR (SNP) | VAF 15/123 reads (12%) | called by muse, mutect2, varscan2
- MFN2 | c.2069+17G>T | Intron (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- NLGN4X | c.*549G>A | 3'UTR (SNP) | VAF 45/108 reads (42%) | catalogued as rs935052626; called by muse, mutect2, varscan2
- NTRK2 | c.1397-56567G>A | Intron (SNP) | VAF 66/136 reads (49%) | catalogued as rs201221612, COSV52857899; called by muse, mutect2, varscan2
- OPN4 | c.-146C>T | 5'UTR (SNP) | VAF 8/25 reads (32%) | catalogued as rs781573936; called by muse, mutect2, varscan2
- PLSCR4 | c.*1567A>T | 3'UTR (SNP) | VAF 55/122 reads (45%) | called by muse, mutect2, varscan2
- PRKCB | c.1864-2039G>T | Intron (SNP) | VAF 17/111 reads (15%) | called by muse, mutect2, varscan2
- RAB40C | c.*128C>T | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by mutect2, varscan2
- RNF2 | c.*542C>G | 3'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- RNF213 | c.10304-136G>T | Intron (SNP) | VAF 74/169 reads (44%) | called by muse, mutect2, varscan2
- RNU6-1224P | chr8:102529481 G>C | 3'Flank (SNP) | VAF 27/205 reads (13%) | called by muse, mutect2, varscan2
- SEL1L | c.*2717_*2718insC | 3'UTR (INS) | VAF 32/90 reads (36%) | called by pindel, varscan2
- SEL1L | c.*2685T>G | 3'UTR (SNP) | VAF 46/98 reads (47%) | called by muse, varscan2
- SELENOM | c.129+70G>A | Intron (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- SERP2 | c.158-6717T>C | Intron (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- SESTD1 | c.*4815A>G | 3'UTR (SNP) | VAF 98/242 reads (40%) | called by muse, mutect2, varscan2
- SH3RF3 | c.*2959G>A | 3'UTR (SNP) | VAF 23/62 reads (37%) | catalogued as rs1303542165; called by muse, mutect2, varscan2
- SHANK3 | c.2009-46C>T | Intron (SNP) | VAF 13/34 reads (38%) | catalogued as rs767314767; called by muse, mutect2, varscan2
- SIM1 | c.*537T>C | 3'UTR (SNP) | VAF 52/112 reads (46%) | called by muse, mutect2, varscan2
- SLC38A2 | c.117-115A>G | Intron (SNP) | VAF 23/83 reads (28%) | called by muse, mutect2, varscan2
- SLITRK4 | chrX:143627493 A>C | 3'Flank (SNP) | VAF 40/100 reads (40%) | called by mutect2, varscan2
- STK16 | c.*912T>C | 3'UTR (SNP) | VAF 57/143 reads (40%) | called by muse, mutect2, varscan2
- SV2A | c.-138dup | 5'UTR (INS) | VAF 26/50 reads (52%) | catalogued as rs1365759790; called by mutect2, varscan2
- TBX18 | c.*21A>G | 3'UTR (SNP) | VAF 21/39 reads (54%) | catalogued as COSV100858428; called by muse, mutect2, varscan2
- TDO2 | c.*258A>T | 3'UTR (SNP) | VAF 39/104 reads (38%) | called by muse, mutect2, varscan2
- THBS1 | c.*3781A>G | 3'UTR (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2
- TOR2A | c.*443G>T | 3'UTR (SNP) | VAF 11/45 reads (24%) | called by muse, mutect2, varscan2
- TRIM69 | c.-102C>G | 5'UTR (SNP) | VAF 20/122 reads (16%) | called by muse, mutect2, varscan2
